Somatic mutation profile of tumor specimen TARGET-10-PARSET-09A (aliquot TARGET-10-PARSET-09A-01D) from TARGET case TARGET-10-PARSET, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,986 days).
Specimen TARGET-10-PARSET-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60ce9422-f2cc-42f8-892f-de82c10daf73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSET-10A (Blood Derived Normal), aliquot TARGET-10-PARSET-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/095a3f36-82c6-4c29-be0b-26eec397e9a5

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1067G>T p.C356F | Missense Mutation (SNP) | VAF 141/291 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50535898; called by muse, mutect2, varscan2
- DLG1 | c.2051C>A p.S684Y (on ENST00000419354 / NM_001290983.1; = p.S706Y on NM_004087.2) | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs749786841, COSV58393098; called by muse, mutect2, varscan2
- EZH2 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 157/331 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57464823; called by muse, mutect2, varscan2
- MAGI1 | c.3473C>T p.A1158V (on ENST00000402939 / NM_001033057.2; = p.A1187V on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1210816472, COSV58315495; called by muse, mutect2, varscan2
- OR4C3 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 104/212 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs143149253; called by muse, mutect2, varscan2
- PCLO | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.074); catalogued as rs766161846, COSV61675800; called by muse, mutect2, varscan2
- ZSCAN9 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV52851108; called by muse, mutect2, varscan2
- RUNX1 | c.967_968insTCTC p.P323Lfs*251 (on ENST00000344691 / NM_001001890.3; = p.P350Lfs*251 on NM_001754.5) | Frame Shift Ins (INS) | VAF 50/126 reads (40%) | called by mutect2, pindel, varscan2
- CFAP221 | c.2196G>A p.P732= | Silent (SNP) | VAF 67/145 reads (46%) | catalogued as rs997981366, COSV54655132; called by muse, mutect2, varscan2
- TNS1 | c.3585C>T p.F1195= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as rs560418128, COSV50693283; called by muse, mutect2, varscan2
